Gene-level copy-number profile of specimen HCM-BROD-0096-C15-85C from HCMI case HCM-BROD-0096-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 48.6 years (17,748 days).
Specimen HCM-BROD-0096-C15-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d7ca5860-53eb-4752-aff2-76a14731fc1e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0096-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/9a8606ad-e2e0-4513-99b6-ab2ac3003bf6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 316; copy number 1: 1,025; copy number 2: 17,997; copy number 3: 30,591; copy number 4: 8,651; copy number 5: 110; copy number 6: 16; copy number 7: 25; copy number 9: 6; copy number 10: 1; copy number 13: 18; copy number 16: 2; copy number 17: 5; copy number 22: 9; copy number 24: 6; copy number 27: 20; copy number 29: 23; copy number 30: 11; copy number 33: 51; copy number 73: 13; copy number 160: 12.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:90,174,062–90,175,865, 1 gene (within-gene range 0–3): CICP25.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 202 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,811,359–143,825,837, 1 gene, copy number 10: AC239798.1.
- chr8:7,355,517–7,601,267, 18 genes, copy number 13: ZNF705G, DEFB108C, DEFB4B, HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1.
- chr8:7,793,716–7,952,413, 11 genes, copy number 9–29: PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A.
- chr8:8,059,572–8,199,973, 1 gene, copy number 7 (within-gene range 3–7): AC105233.4.
- chr8:8,116,745–8,226,614, 4 genes, copy number 7: SNRPCP17, ENPP7P1, FAM85B, AC068020.1.
- chr8:9,555,144–13,604,610, 126 genes, copy number 7–33 (within-gene range 4–36) (broad region; genes not listed).
- chr12:24,949,163–26,335,856, 36 genes, copy number 30–160 (within-gene range 2–160): AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3.
- chr16:35,021,749–35,085,060, 5 genes, copy number 17 (within-gene range 2–17): AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11.

Autosomal genes at a single copy (total copy number 1): 1,021. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
